CCDI case PBBSXV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/626a71f2-c052-4f07-9579-bb5975520f8e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.8 years (5,046 days).

Biospecimens (4 samples)
- Sample 0DG9FR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DG9JF, 0DG9ME (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGBC8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
